Somatic mutation profile of tumor specimen 66b829db-1cdd-460d-b2f3-0e9ca9 (aliquot 66b829db-1cdd-460d-b2f3-0e9ca9_D6_1) from CPTAC case 05CO053, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 66b829db-1cdd-460d-b2f3-0e9ca9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93cee0e3-58de-4414-a252-b22439f1bd88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen acefec8a-32a0-4686-a421-6d12d5 (Blood Derived Normal), aliquot acefec8a-32a0-4686-a421-6d12d5_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404bec6f-c00b-4cf0-9881-1786a43909a1

The open-access MAF lists 122 somatic variants for this specimen: 84 protein-altering or splice-affecting, 31 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 31, Nonsense Mutation 8, Frame Shift Ins 5, Intron 5, RNA 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 41/180 reads (23%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as rs267606865, CM103401, COSV65185774, COSV65195022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 93/306 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV57325808, COSV57358074; called by muse, mutect2, varscan2
- ATG9B | c.2529G>C p.Q843H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753925921, COSV52486610; called by muse, mutect2, varscan2
- ATP13A1 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs973955925, COSV52284834; called by muse, mutect2, varscan2
- COL6A5 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs764962068, COSV55202626; called by muse, mutect2, varscan2
- CSMD1 | c.1724C>A p.S575Y (on ENST00000520002; = p.S574Y on NM_033225.6) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1206467188; called by muse, mutect2, varscan2
- DIS3L | c.725G>A p.R242H (on ENST00000319212 / NM_001143688.3; = p.R159H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs139490064, COSV59914405; called by muse, mutect2, varscan2
- DOCK2 | c.4181C>T p.P1394L | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56944361, COSV56970280; called by muse, mutect2, varscan2
- DPYSL5 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1264741552; called by muse, mutect2, varscan2
- DPYSL5 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs755205638, COSV56512346, COSV99982937; called by muse, mutect2
- ENOX2 | c.1174G>T p.E392* (on ENST00000338144 / NM_001382520.1; = p.E363* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as rs1351165843; called by muse, mutect2
- FSTL4 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs760609240; called by muse, mutect2, varscan2
- GUCY1A1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 63/246 reads (26%) | catalogued as COSV56653135; called by muse, mutect2, varscan2
- HS3ST3A1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs1299495331; called by muse, mutect2, varscan2
- KDM4A | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64960411; called by muse, mutect2, varscan2
- KRTAP8-1 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.763); catalogued as rs1425980141, COSV100297883, COSV61597793; called by muse, mutect2, varscan2
- LRFN5 | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1244908019, COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- LRP5 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM153241; called by muse, mutect2, varscan2
- MAGEB3 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100854588, COSV100854764; called by muse, mutect2, varscan2
- MRPL38 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs371715586; called by muse, mutect2, varscan2
- MSLN | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs765504641; called by muse, mutect2, varscan2
- MYH3 | c.4913C>T p.A1638V | Missense Mutation (SNP) | VAF 102/343 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.783); catalogued as rs1316332773; called by muse, mutect2, varscan2
- MYOG | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 122/527 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99614005; called by muse, mutect2, varscan2
- NLRP2 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as rs767901107, COSV54752314, COSV99672463; called by muse, mutect2, varscan2
- OOSP1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs1448103745, COSV67527445; called by muse, mutect2, varscan2
- PCDHGA6 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 30/612 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs540188136, COSV53997585; called by muse, mutect2
- PIAS4 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs748059852; called by muse, mutect2, varscan2
- PRAM1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs534829677; called by muse, mutect2, varscan2
- PRR23C | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs1457133253; called by muse, mutect2, varscan2
- RADX | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs766967950; called by muse, mutect2, varscan2
- RFPL4B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 114/495 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs764420783, COSV101480716; called by muse, mutect2, varscan2
- RNF128 | c.31dup p.W11Lfs*11 | Frame Shift Ins (INS) | VAF 13/40 reads (33%) | catalogued as rs757038390; called by mutect2, varscan2
- SLC12A7 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs373761333; called by muse, mutect2, varscan2
- SNF8 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs775611332; called by muse, mutect2, varscan2
- TIMD4 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139335693; called by muse, mutect2, varscan2
- TMPRSS6 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as rs761779631; called by muse, mutect2, varscan2
- TNR | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746255492, COSV99691328; called by muse, mutect2, varscan2
- TRAPPC2L | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as rs766487032; called by muse, mutect2, varscan2
- UPP1 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761983133, COSV100080973; called by muse, mutect2, varscan2
- VRK3 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 91/358 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs776497793, COSV57464215; called by muse, mutect2, varscan2
- WNT2B | c.517C>A p.R173S (on ENST00000369684 / NM_024494.3; = p.R154S on NM_004185.4) | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs756133300; called by muse, mutect2
- WNT3A | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs774063132; called by muse, mutect2, varscan2
- ZBBX | c.975del p.K325Nfs*55 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs773705832; called by mutect2, pindel
- ZBTB16 | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 66/670 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100251911, COSV60090006, COSV60099514; called by muse, mutect2
- AC024598.1 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO7 | c.1610T>C p.L537P (on ENST00000274979; = p.L483P on NM_001370694.2) | Missense Mutation (SNP) | VAF 116/422 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATP5IF1 | c.216dup p.H73Tfs*3 | Frame Shift Ins (INS) | VAF 52/138 reads (38%) | called by mutect2, pindel, varscan2
- CCDC168 | c.17437dup p.I5813Nfs*29 | Frame Shift Ins (INS) | VAF 60/233 reads (26%) | called by mutect2, varscan2
- COL5A1 | c.1860G>A p.M620I | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ECT2L | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 58/480 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFEMP1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EVC2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FAM3D | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- GAK | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GIGYF2 | c.2564A>G p.E855G | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- HOMER2 | c.388-7T>A | Splice Region (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- HYOU1 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 76/297 reads (26%) | called by muse, mutect2, varscan2
- ILK | c.622T>A p.W208R | Missense Mutation (SNP) | VAF 72/786 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- INSYN2B | c.775T>G p.L259V | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- KLRC2 | c.23_24insA p.F8Lfs*18 | Frame Shift Ins (INS) | VAF 47/206 reads (23%) | called by pindel, varscan2
- LRRC8C | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 109/424 reads (26%) | called by muse, mutect2, varscan2
- MRPL22 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated, low confidence (0.65); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NFATC3 | c.1060A>T p.K354* | Nonsense Mutation (SNP) | VAF 39/144 reads (27%) | called by muse, mutect2, varscan2
- NWD1 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- RUNDC3B | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RYR3 | c.6238G>C p.E2080Q | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.202); called by muse, varscan2
- SERPINB13 | c.226-2A>G p.X76_splice | Splice Site (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- SLC6A3 | c.904T>A p.F302I | Missense Mutation (SNP) | VAF 54/518 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC6A4 | c.1606T>C p.F536L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- SMG1 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- TAOK3 | c.2462A>C p.E821A | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- TMEM250 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 6/160 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIP12 | c.4758G>T p.L1586F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- TTN | c.81189C>A p.S27063R (on ENST00000591111; = p.S19639R on NM_003319.4) | Missense Mutation (SNP) | VAF 102/402 reads (25%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.71297G>A p.G23766E (on ENST00000591111; = p.G16342E on NM_003319.4) | Missense Mutation (SNP) | VAF 53/215 reads (25%) | PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- UBR2 | c.3684A>T p.R1228S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UFL1 | c.1331A>T p.K444I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- USP26 | c.2304C>A p.H768Q | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- UTP20 | c.7727G>C p.S2576T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIC3 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 105/183 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ZNF107 | c.1482dup p.P495Tfs*3 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- ZNF471 | c.1832A>G p.K611R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA13 | c.10593C>T p.I3531= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as rs774232587; called by muse, mutect2, varscan2
- ADGRB1 | c.129C>T p.C43= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1324200602; called by muse, mutect2, varscan2
- ARHGAP28 | c.1839C>T p.L613= (on ENST00000383472 / NM_001366230.1; = p.L454= on NM_001010000.3) | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs778345367, COSV51637761; called by muse, mutect2
- B3GNT6 | c.714G>A p.A238= | Silent (SNP) | VAF 72/249 reads (29%) | called by muse, mutect2, varscan2
- CADM3 | c.1047C>T p.I349= (on ENST00000368125 / NM_001127173.3; = p.I383= on NM_021189.5) | Silent (SNP) | VAF 102/356 reads (29%) | called by muse, mutect2, varscan2
- CDC27 | c.207G>A p.P69= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs148510863, COSV50680405; called by muse, mutect2, varscan2
- CSNK2A3 | c.78C>T p.Y26= | Silent (SNP) | VAF 124/450 reads (28%) | catalogued as COSV57153512; called by muse, varscan2
- CYREN | c.441G>A p.V147= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as rs1220470402; called by muse, varscan2
- DDX60 | c.4989A>G p.G1663= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- FAT4 | c.11370G>A p.E3790= | Silent (SNP) | VAF 97/351 reads (28%) | called by muse, mutect2, varscan2
- GUCY2C | c.552T>G p.T184= | Silent (SNP) | VAF 28/295 reads (9%) | catalogued as COSV99664139; called by muse, mutect2
- ITGA8 | c.1158C>T p.F386= | Silent (SNP) | VAF 83/273 reads (30%) | catalogued as rs763576378, COSV65226540, COSV65227301; called by muse, mutect2, varscan2
- JAG2 | c.3579G>A p.A1193= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as rs776732182, COSV59309333; called by muse, mutect2, varscan2
- KBTBD4 | c.831C>T p.I277= | Silent (SNP) | VAF 69/253 reads (27%) | called by muse, mutect2, varscan2
- KIF19 | c.45G>A p.A15= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs746362776; called by muse, mutect2, varscan2
- LRP8 | c.906C>T p.D302= | Silent (SNP) | VAF 58/189 reads (31%) | catalogued as rs757325426, COSV60099827; called by muse, mutect2, varscan2
- MARF1 | c.3675C>T p.I1225= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs368752613; called by muse, mutect2, varscan2
- MS4A4E | c.249G>A p.A83= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs562944261, COSV67518377; called by muse, mutect2, varscan2
- MSH5 | c.831G>A p.P277= | Silent (SNP) | VAF 68/196 reads (35%) | catalogued as rs148428889; called by muse, mutect2, varscan2
- NCAM1 | c.1797G>A p.A599= (on ENST00000316851 / NM_181351.5; = p.A589= on NM_000615.7) | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as rs374753347; called by muse, mutect2, varscan2
- OR4C11 | c.252C>A p.L84= | Silent (SNP) | VAF 44/297 reads (15%) | called by muse, mutect2, varscan2
- PAK5 | c.2118G>A p.P706= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as rs141022343; called by muse, mutect2, varscan2
- PRKCB | c.1695C>A p.S565= | Silent (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- RIPOR3 | c.66C>T p.S22= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs771138078, COSV50386659; called by muse, mutect2, varscan2
- SLC24A4 | c.1824C>T p.N608= | Silent (SNP) | VAF 74/247 reads (30%) | catalogued as rs1311467632, COSV54120834; called by muse, mutect2, varscan2
- SLC6A13 | c.363C>T p.I121= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs1019258407; called by muse, mutect2, varscan2
- SOX17 | c.459C>A p.G153= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs1198850480, COSV52027621, COSV52029053; called by muse, mutect2, varscan2
- TRBV5-1 | c.30G>T p.L10= | Silent (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- TRIM58 | c.48C>T p.C16= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1202442605, COSV63569929; called by muse, mutect2, varscan2
- USP19 | c.2184G>T p.L728= | Silent (SNP) | VAF 62/181 reads (34%) | called by muse, mutect2, varscan2
- WDR88 | c.309C>T p.H103= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs772808209; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3317-18C>T | Intron (SNP) | VAF 55/215 reads (26%) | called by muse, mutect2, varscan2
- DNAH14 | c.9205+6143T>C | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- IL17RC | c.975+49G>A | Intron (SNP) | VAF 77/297 reads (26%) | called by muse, mutect2, varscan2
- POMGNT1 | c.1539+27_1539+28del | Intron (DEL) | VAF 118/546 reads (22%) | called by pindel, varscan2
- SP140 | c.237+21G>C | Intron (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- TXLNGY | n.5062C>T | RNA (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- ZNF658B | n.2832C>T | RNA (SNP) | VAF 12/252 reads (5%) | catalogued as rs1395944774; called by muse, mutect2
